Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4837, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4837-01A (Primary Tumor).

FINAL DIAGNOSIS:

TCGA-B0-4837

KIDNEY, LEFT, RADICAL NEPHRECTOMY:

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE
- B. FUHRMAN'S NUCLEAR GRADE IS III OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 6.0 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY REVEALS CHRONIC INFLAMMATION, ARTERIAL SCLEROSIS AND FOCAL HYALINIZATION OF GLOMERULI.
- I. THE ADRENAL GLAND IS NOT SUBMITTED.
- J. TNM STAGE: p T1b Nx MX.

Source: NCI Genomic Data Commons file 8888fd49-0e99-4177-af97-cf14b21ebe7c (TCGA-B0-4837.5CCC5A6D-F54F-4A78-A7B6-D0A05C46C623.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).